Somatic mutation profile of tumor specimen 0DOA3P from CCDI case PBCBRX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Myxofibrosarcoma; Tissue or organ of origin: Scrotum, NOS; Age at diagnosis: 15.3 years (5,578 days).
Specimen 0DOA3P: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8ef0ef35-7a7f-4bad-999a-83f6df1378c0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DOA26 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cdcf0692-86b3-4e8a-8f97-bc7cb76fe506

The open-access MAF lists 8 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 2, 3'UTR 2, Missense Mutation 2, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRK | c.1052C>A p.A351D | Missense Mutation (SNP) | VAF 150/163 reads (92%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR10H4 | c.213G>C p.E71D | Missense Mutation (SNP) | VAF 96/392 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- PCM1 | c.4822T>C p.L1608= | Silent (SNP) | VAF 159/496 reads (32%) | called by muse, mutect2, varscan2
- STXBP5L | c.3339G>A p.A1113= | Silent (SNP) | VAF 185/463 reads (40%) | catalogued as rs150797963; called by muse, mutect2, varscan2
- GCFC2 | c.1145-91T>A | Intron (SNP) | VAF 4/54 reads (7%) | called by muse, mutect2
- OR9A4 | c.*70C>A | 3'UTR (SNP) | VAF 4/23 reads (17%) | called by muse, mutect2, varscan2
- ZBED3 | c.-2del | 5'UTR (DEL) | VAF 34/118 reads (29%) | called by mutect2, varscan2
- ZNF365 | c.*53del | 3'UTR (DEL) | VAF 4/36 reads (11%) | called by mutect2, varscan2
